Gene-level copy-number profile of tumor specimen ALCH-ADW3-TTP1-A from ALCHEMIST case ALCH-ADW3, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 63.3 years (23,118 days).
Specimen ALCH-ADW3-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f1083d8f-290a-4fcb-a408-e847eebc5b25.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADW3-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/48b96d54-9283-4428-a2db-76a5f3d3f8c7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 23; copy number 1: 2,410; copy number 2: 55,935; copy number 3: 512; copy number 4: 7; copy number 5: 5; copy number 6: 2; copy number 7: 16.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:3,205,988–3,208,664, 1 gene (within-gene range 0–2): AL512383.1.
- chr1:113,168,994–113,169,403, 1 gene: AL357055.1.
- chr6:34,219,439–34,220,066, 1 gene: CYCSP55.
- chr17:72,642,731–72,644,490, 1 gene: AC080037.2.
- chr19:49,361,783–49,388,091, 2 genes (within-gene range 0–2): DKKL1, AC010643.1.
- chr22:33,014,980–33,015,461, 1 gene (within-gene range 0–2): Z83846.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 23 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:850,291–892,801, 1 gene, copy number 6 (within-gene range 1–6): BRD9.
- chr13:72,567,213–73,661,891, 18 genes, copy number 5–7: AL356754.2, AL356754.1, RPL21P110, RNU6-80P, MZT1, BORA, DIS3, PIBF1, RNU6-79P, PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, LINC00393, LINC00392.
- chr14:105,583,731–105,588,395, 1 gene, copy number 6: IGHA2.
- chr14:105,620,506–105,626,066, 1 gene, copy number 5 (within-gene range 1–5): IGHG4.
- chr14:105,639,559–105,644,790, 2 genes, copy number 5 (within-gene range 3–5): IGHG2, MIR8071-2.

Autosomal genes at a single copy (total copy number 1): 88. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
